CPTAC case C3N-03210 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/af611aef-c369-4941-959e-a68838e2b2f2

Demographics
Sex at birth: male; Race: asian; Year of birth: 1966; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 51.5 years (18,827 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T1c; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,810 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,810 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 34; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 362 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 664 days (1.8 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,015 days (2.8 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,355 days (3.7 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,810 days (5.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 79 kg; Height: 175 cm; BMI: 25.8; FEV1/FVC before bronchodilator (%): 99.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 27; Cigarettes per day: 20; Tobacco smoking onset year: 1990; Tobacco smoking quit year: 2017; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 27.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03210-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 131 mg; Time between clamping and freezing: 23 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03210-22: Section location: Left Lower Lobe; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-03210-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 235 mg; Time between clamping and freezing: 23 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03210-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
